Somatic mutation profile of tumor specimen TCGA-BR-7716-01A (aliquot TCGA-BR-7716-01A-21D-2053-08) from TCGA case TCGA-BR-7716, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 62.5 years (22,829 days).
Specimen TCGA-BR-7716-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 665b6caa-5b2f-4fab-a567-bca2280294f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-7716-10A (Blood Derived Normal), aliquot TCGA-BR-7716-10A-01D-2053-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3632ab9-009f-4e3b-981d-7f222a7008ce

The open-access MAF lists 161 somatic variants for this specimen: 125 protein-altering or splice-affecting, 36 silent.
By variant classification: Missense Mutation 108, Silent 36, Nonsense Mutation 13, Frame Shift Del 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABCB5 | c.3518A>C p.K1173T (on ENST00000404938 / NM_001163941.2; = p.K728T on NM_178559.6) | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV51716859; called by muse, mutect2, varscan2
- AGAP1 | c.1445G>C p.S482T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV58335571; called by muse, mutect2, varscan2
- AHNAK2 | c.9884C>G p.S3295C | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.796); catalogued as COSV60924833; called by muse, mutect2, varscan2
- AHNAK2 | c.9389C>G p.S3130C | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs568837822, COSV60924844; called by muse, mutect2
- ANKRD49 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.098); catalogued as COSV57060538; called by muse, varscan2
- ANKRD7 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV54556110; called by muse, mutect2
- ARHGAP36 | c.902T>A p.M301K | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV52270269; called by muse, mutect2, varscan2
- ARHGEF17 | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs575665175, COSV99736247; called by muse, mutect2, varscan2
- ASB3 | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.755); catalogued as COSV54858543; called by muse, mutect2, varscan2
- BARHL2 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.023); catalogued as COSV100966081; called by muse, mutect2, varscan2
- BCAN | c.730G>T p.D244Y | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100228352; called by muse, mutect2
- BTNL8 | c.1021C>T p.H341Y | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs763420925, COSV51460590, COSV51462320; called by muse, mutect2, varscan2
- CACNA1G | c.3427G>A p.E1143K | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1446496697, COSV61734565; called by muse, mutect2
- CD163 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs201732077, COSV63135400; called by muse, mutect2, varscan2
- CDIPT | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV54889514; called by muse, mutect2
- CHD4 | c.4708G>T p.V1570F (on ENST00000357008 / NM_001363606.2; = p.V1583F on NM_001273.5) | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.118); catalogued as COSV58907844; called by muse, mutect2
- CHD6 | c.1271A>C p.K424T | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as rs374043976; called by muse, mutect2, varscan2
- CLIP4 | c.1244C>T p.T415I | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV60751358; called by muse, mutect2
- CLPTM1L | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV57991981; called by muse, mutect2
- COMMD3 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV100936449; called by muse, mutect2
- CPA2 | c.965A>C p.K322T | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as COSV55980823; called by muse, mutect2, varscan2
- DNMBP | c.2855A>T p.N952I | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV60630547; called by muse, mutect2, varscan2
- DNMT1 | c.1054A>G p.K352E | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV61582175; called by muse, mutect2, varscan2
- DPP3 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57857440; called by muse, mutect2, varscan2
- ECPAS | c.4213G>T p.D1405Y | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52204412; called by muse, mutect2, varscan2
- ENOX1 | c.23A>G p.E8G | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as COSV54911512; called by muse, mutect2, varscan2
- EPHA6 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV67566492; called by muse, mutect2, varscan2
- EPHA8 | c.823G>C p.A275P | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.603); catalogued as COSV51283996; called by muse, mutect2, varscan2
- ERF | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV55897023, COSV99724408; called by muse, mutect2
- EXOC1 | c.1372G>C p.E458Q | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.212); catalogued as rs1459015032, COSV62121450; called by muse, mutect2, varscan2
- FAM83F | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV61000896; called by muse, mutect2, varscan2
- FAT2 | c.10492C>G p.Q3498E | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV55826388; called by muse, mutect2
- FAT3 | c.9136A>G p.K3046E | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as rs752304278, COSV53154720; called by muse, mutect2, varscan2
- GABRG2 | c.1028C>A p.A343D (on ENST00000361925 / NM_001375343.1; = p.A303D on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62720996; called by muse, mutect2, varscan2
- GGA1 | c.1077C>G p.D359E | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.9); PolyPhen benign (0.084); catalogued as COSV57331275; called by muse, mutect2, varscan2
- HELZ | c.2195G>A p.R732H | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV62380085; called by muse, mutect2, varscan2
- HSP90AA1 | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV53490598; called by muse, mutect2
- HTR1F | c.976G>T p.E326* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV60390863; called by muse, mutect2
- HTR5A | c.579G>T p.Q193H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.984); catalogued as COSV99839734; called by muse, mutect2, varscan2
- KBTBD4 | c.1153G>T p.G385W | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748459776, COSV58597668; called by muse, mutect2, varscan2
- KCND3 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56180221; called by muse, mutect2, varscan2
- KIAA2026 | c.3588A>T p.L1196F | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV67356912; called by muse, mutect2, varscan2
- KMT2E | c.1964C>G p.S655C | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV57577672; called by muse, mutect2, varscan2
- L1CAM | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as CM064084, COSV62829504; called by muse, mutect2, varscan2
- MACF1 | c.1759C>T p.R587* | Nonsense Mutation (SNP) | VAF 30/192 reads (16%) | catalogued as COSV58361762; called by muse, mutect2, varscan2
- MAGEE1 | c.1719A>C p.E573D | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.257); catalogued as COSV63911586; called by muse, mutect2, varscan2
- MMP27 | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV52782092; called by muse, mutect2, varscan2
- MRNIP | c.906G>T p.K302N | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV52974663; called by muse, mutect2, varscan2
- MRPL3 | c.185A>T p.K62M | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV53915679; called by muse, mutect2, varscan2
- MUC16 | c.26339C>A p.T8780K | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.053); catalogued as COSV67482685; called by muse, mutect2, varscan2
- NAA25 | c.2529C>A p.F843L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.084); catalogued as COSV55702521; called by muse, varscan2
- NAA25 | c.2248C>T p.Q750* | Nonsense Mutation (SNP) | VAF 6/124 reads (5%) | catalogued as COSV55707425; called by muse, mutect2
- NCAM2 | c.1105G>C p.D369H | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.594); catalogued as COSV53066927, COSV53094159; called by muse, mutect2, varscan2
- NFKB2 | c.436A>G p.M146V | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.1); catalogued as COSV51874524; called by muse, mutect2, varscan2
- NHS | c.4816C>T p.Q1606* | Nonsense Mutation (SNP) | VAF 23/110 reads (21%) | catalogued as COSV66279898; called by muse, mutect2, varscan2
- NOL4 | c.1279G>A p.V427I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as COSV52356313; called by muse, mutect2, varscan2
- NPTX2 | c.1003G>T p.G335W | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99675040; called by muse, mutect2, varscan2
- NUTM2D | c.792G>A p.W264* | Nonsense Mutation (SNP) | VAF 24/120 reads (20%) | catalogued as COSV101097006; called by mutect2, varscan2
- OPCML | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.021); catalogued as rs1012703187, COSV59406450; called by muse, mutect2, varscan2
- OR1Q1 | c.534C>G p.F178L | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV52918133, COSV52918740; called by muse, mutect2
- OR2AK2 | c.850C>G p.L284V | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as COSV63558323; called by muse, mutect2
- OR4C11 | c.548T>G p.L183W | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100155425; called by muse, mutect2
- OR4S2 | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1211304577, COSV100412742; called by muse, mutect2
- OR5K3 | c.516T>A p.H172Q | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV67350462; called by muse, mutect2, varscan2
- P2RY10 | c.38T>A p.M13K | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV50684197; called by muse, mutect2, varscan2
- PASD1 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.148); catalogued as COSV64856909; called by muse, mutect2, varscan2
- PDE4DIP | c.6701G>A p.R2234Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs748397848, COSV57718586; called by mutect2, varscan2
- PDE8B | c.569T>G p.F190C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV53742649; called by muse, mutect2, varscan2
- PMFBP1 | c.2584C>A p.L862I (on ENST00000537465; = p.L857I on NM_031293.3) | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV52829551; called by muse, mutect2
- PMM2 | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51633648; called by muse, mutect2, varscan2
- POLQ | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV51747673, COSV51761701; called by muse, mutect2
- POU3F4 | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.487); catalogued as COSV64540501; called by muse, mutect2, varscan2
- PRKCG | c.1492G>A p.D498N | Missense Mutation (SNP) | VAF 46/517 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54731137; called by muse, mutect2
- PRMT9 | c.1606G>T p.G536C | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV59360797; called by muse, mutect2, varscan2
- PSMC1 | c.1083G>C p.K361N | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV54321717; called by muse, mutect2, varscan2
- RACK1 | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); catalogued as COSV59321501; called by muse, mutect2, varscan2
- RAI1 | c.104A>T p.Q35L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV55397005; called by muse, mutect2, varscan2
- RASGRF2 | c.2500G>A p.A834T | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV54136202; called by muse, mutect2, varscan2
- SAMD9 | c.1447C>G p.L483V | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV101180260, COSV66076996; called by muse, mutect2
- SBF1 | c.5151T>C p.R1717= | Splice Region (SNP) | VAF 16/71 reads (23%) | catalogued as rs779453976, COSV53296757; called by muse, mutect2, varscan2
- SEPHS1 | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 62/588 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV59257243, COSV59260027; called by muse, mutect2, varscan2
- SF3B3 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 17/185 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.501); catalogued as COSV56790038; called by muse, mutect2
- SIRPA | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61540974; called by muse, mutect2
- SLC4A1AP | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs770113505, COSV58136721; called by muse, mutect2, varscan2
- SLC7A14 | c.1046G>T p.S349I | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763192459, COSV51587200; called by muse, mutect2
- SLC9A2 | c.1817C>G p.S606* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as COSV52135840; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2194T>G p.L732V (on ENST00000540229 / NM_001371097.1; = p.L671V on NM_001009562.4) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.258); catalogued as COSV101044619, COSV67444086; called by muse, mutect2, varscan2
- SLFNL1 | c.403A>C p.S135R | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as COSV57235315; called by muse, mutect2
- SMG9 | c.844C>G p.L282V | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.558); catalogued as COSV54215886; called by muse, mutect2
- SNX8 | c.290T>G p.V97G | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56129156; called by muse, mutect2, varscan2
- SOX17 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52027354; called by muse, mutect2, varscan2
- SPRR1B | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 32/237 reads (14%) | catalogued as COSV61067987; called by muse, mutect2, varscan2
- SPTA1 | c.5821G>T p.E1941* | Nonsense Mutation (SNP) | VAF 10/148 reads (7%) | catalogued as COSV63757433; called by muse, mutect2
- SPTLC2 | c.511A>G p.I171V | Missense Mutation (SNP) | VAF 70/223 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.268); catalogued as rs763924228, COSV53642140; called by muse, mutect2, varscan2
- SULT2A1 | c.829C>T p.L277F | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.091); catalogued as COSV55765797; called by muse, mutect2, varscan2
- TLN2 | c.128C>T p.T43I | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV60893598; called by muse, mutect2
- TMEM200A | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as rs538005580, COSV99759727; called by muse, mutect2, varscan2
- TMPRSS15 | c.2917G>T p.G973* | Nonsense Mutation (SNP) | VAF 34/181 reads (19%) | catalogued as COSV53045694; called by muse, mutect2, varscan2
- TRMT6 | c.512T>A p.M171K | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV52544755; called by muse, mutect2, varscan2
- TRPM6 | c.2052C>G p.F684L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV62519006; called by muse, mutect2, varscan2
- TRPS1 | c.2464G>T p.E822* (on ENST00000220888 / NM_001330599.2; = p.E835* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 60/138 reads (43%) | catalogued as COSV55255308; called by muse, mutect2, varscan2
- TTC21B | c.2153G>C p.R718T | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as COSV54633359; called by muse, mutect2, varscan2
- TTN | c.3174G>C p.E1058D (on ENST00000591111; = p.E1012D on NM_003319.4) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | PolyPhen probably damaging (0.99); catalogued as COSV60245400; called by muse, mutect2, varscan2
- USH2A | c.15581G>A p.R5194H | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs727505155, COSV52065509; ClinVar: likely benign / uncertain significance; called by muse, varscan2
- USP24 | c.5156C>T p.S1719L | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV53774863; called by muse, mutect2
- USP7 | c.3212C>T p.S1071F | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV61216572; called by muse, mutect2, varscan2
- USP7 | c.1062C>G p.I354M | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61216582; called by muse, mutect2
- USP7 | c.351C>A p.F117L | Missense Mutation (SNP) | VAF 41/277 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV61215663, COSV61216589; called by muse, mutect2, varscan2
- VEPH1 | c.279C>G p.N93K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.251); catalogued as rs532806977, COSV62881446; called by muse, mutect2, varscan2
- VN1R4 | c.827G>T p.C276F | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.222); catalogued as COSV100237510; called by muse, mutect2
- VPS13A | c.5032G>T p.E1678* | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | catalogued as COSV62435654; called by muse, mutect2, varscan2
- VPS9D1 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV66995041; called by muse, mutect2
- VSIG8 | c.86A>G p.Q29R | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.253); catalogued as rs779962886, COSV100928823; called by mutect2, varscan2
- VTI1B | c.676T>C p.Y226H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV53620561; called by muse, mutect2, varscan2
- ZCCHC8 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1327102590, COSV60319422; called by muse, mutect2
- ZNF229 | c.1922C>G p.S641* | Nonsense Mutation (SNP) | VAF 13/161 reads (8%) | catalogued as COSV52163975, COSV52164382; called by muse, mutect2
- ZNF492 | c.1408A>T p.I470F | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV71762265; called by muse, mutect2, varscan2
- ZNF521 | c.889A>T p.M297L | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64130267; called by mutect2, varscan2
- ZNF599 | c.405G>C p.L135F | Missense Mutation (SNP) | VAF 15/231 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV61396961; called by muse, mutect2
- ZNF75A | c.663G>A p.W221* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV104439242, COSV73039673; called by muse, mutect2, varscan2
- HNRNPC | c.563-3_563-2del p.X188_splice (on ENST00000420743; = p.X175_splice on NM_004500.4 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 10/53 reads (19%) | called by mutect2, pindel, varscan2
- ORC5 | c.268_274del p.C90Lfs*3 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- OTUD4 | c.1131del p.P378Lfs*10 (on ENST00000447906 / NM_001366057.1; = p.P313Lfs*10 on NM_001102653.1) | Frame Shift Del (DEL) | VAF 26/68 reads (38%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.1110G>C p.L370F | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- ADAM20 | c.960T>C p.P320= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV56455994; called by muse, mutect2, varscan2
- ADAMTS4 | c.1110C>T p.L370= | Silent (SNP) | VAF 13/121 reads (11%) | catalogued as COSV100917520; called by muse, mutect2, varscan2
- AFAP1L2 | c.1080G>A p.L360= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV58417595; called by muse, mutect2, varscan2
- AGR2 | c.75C>T p.V25= | Silent (SNP) | VAF 15/136 reads (11%) | catalogued as COSV68597230; called by muse, mutect2, varscan2
- ARHGAP32 | c.5316A>G p.Q1772= (on ENST00000310343 / NM_001378025.1; = p.Q1423= on NM_014715.4) | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as rs968171128, COSV59853243; called by muse, mutect2, varscan2
- C6orf118 | c.882A>G p.E294= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV57817615; called by muse, mutect2
- CAMTA2 | c.2544C>A p.G848= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99236742; called by muse, mutect2, varscan2
- CETN1 | c.405G>A p.E135= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV59120894; called by muse, mutect2, varscan2
- CYB5D2 | c.495G>A p.Q165= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs139874723, COSV56800985; called by muse, mutect2, varscan2
- DUXA | c.498G>A p.A166= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs370297842; called by mutect2, varscan2
- EPHA6 | c.795T>A p.T265= | Silent (SNP) | VAF 31/272 reads (11%) | catalogued as COSV67587200; called by muse, mutect2, varscan2
- FMR1 | c.1314T>C p.D438= | Silent (SNP) | VAF 29/167 reads (17%) | catalogued as COSV54426330; called by muse, mutect2, varscan2
- GPC5 | c.1317C>A p.A439= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV65618284; called by muse, mutect2, varscan2
- LRP4 | c.5193C>T p.L1731= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as COSV66137726; called by muse, mutect2, varscan2
- MEFV | c.2241T>C p.S747= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV54825782; called by muse, mutect2, varscan2
- NIF3L1 | c.1002C>T p.V334= (on ENST00000409020 / NM_001369444.1; = p.V307= on NM_021824.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/138 reads (13%) | catalogued as COSV62900827; called by muse, mutect2, varscan2
- P2RY12 | c.432C>G p.L144= | Silent (SNP) | VAF 7/134 reads (5%) | catalogued as COSV56390971; called by muse, mutect2
- PKHD1 | c.2895A>T p.T965= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV61889574; called by muse, mutect2, varscan2
- PPT1 | c.199T>C p.L67= (on ENST00000433473; = p.L68= on NM_000310.4) | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as COSV65655983; called by muse, mutect2
- PTPRM | c.4206C>T p.I1402= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs1178183506, COSV59874339; called by muse, mutect2, varscan2
- RALGAPA2 | c.477C>T p.F159= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs777875659, COSV52500645; called by muse, mutect2, varscan2
- SHOC1 | c.2796T>C p.Y932= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV59505685; called by muse, mutect2, varscan2
- SNAP23 | c.618G>A p.K206= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as COSV51041844, COSV51042153; called by muse, mutect2, varscan2
- SRGAP1 | c.1107C>G p.L369= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV61901527; called by muse, mutect2, varscan2
- STRADB | c.507G>A p.V169= | Silent (SNP) | VAF 31/209 reads (15%) | catalogued as COSV52045257; called by muse, mutect2, varscan2
- STX6 | c.438G>A p.E146= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as rs1406174891, COSV51113391; called by muse, mutect2
- TFDP3 | c.594G>A p.Q198= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs1382148412, COSV59538033; called by muse, mutect2, varscan2
- TMEM147 | c.243G>T p.L81= | Silent (SNP) | VAF 17/165 reads (10%) | catalogued as COSV52866063, COSV52870579, COSV99382657; called by muse, mutect2, varscan2
- USH2A | c.14466G>A p.L4822= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV56412803; called by muse, mutect2, varscan2
- USP24 | c.3313C>T p.L1105= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs1391392976, COSV99599411; called by muse, mutect2
- USP24 | c.3312T>A p.L1104= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV99600586; called by muse, mutect2
- VIPR2 | c.987C>A p.S329= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV100057870; called by muse, mutect2
- VWCE | c.219C>T p.F73= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs968290070, COSV57110852; called by muse, mutect2, varscan2
- WHRN | c.576C>T p.N192= | Silent (SNP) | VAF 27/128 reads (21%) | catalogued as COSV54331655; called by muse, mutect2, varscan2
- ZBTB17 | c.1749C>T p.I583= | Silent (SNP) | VAF 18/142 reads (13%) | catalogued as COSV65271183; called by muse, mutect2, varscan2
- ZFPM2 | c.3144G>A p.L1048= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV65875173; called by muse, mutect2, varscan2
